Somatic mutation profile of tumor specimen TCGA-EX-A69M-01A (aliquot TCGA-EX-A69M-01A-11D-A32I-09) from TCGA case TCGA-EX-A69M, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 62.7 years (22,917 days).
Specimen TCGA-EX-A69M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34d9f80b-a0f1-4d0e-b69f-3b1185a2615d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EX-A69M-10A (Blood Derived Normal), aliquot TCGA-EX-A69M-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34388f2f-457a-40ce-815b-a8d217e37569

The open-access MAF lists 54 somatic variants for this specimen: 39 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 12, Frame Shift Del 3, Nonsense Mutation 3, Intron 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMZ1 | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs780230622, COSV56685723; called by muse, mutect2, varscan2
- ASPG | c.285C>A p.C95* | Nonsense Mutation (SNP) | VAF 27/63 reads (43%) | catalogued as COSV71933687; called by muse, mutect2
- CA7 | c.190A>G p.N64D | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as COSV58156180; called by muse, mutect2, varscan2
- CBFB | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51997398; called by muse, mutect2, varscan2
- CBLC | c.1133G>A p.W378* | Nonsense Mutation (SNP) | VAF 32/74 reads (43%) | catalogued as COSV54321884; called by muse, mutect2, varscan2
- DISP2 | c.2651C>T p.P884L | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV51117985; called by muse, mutect2, varscan2
- DNAH3 | c.10460C>A p.A3487E | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54511551, COSV54537920; called by muse, mutect2, varscan2
- DNAH7 | c.5177A>T p.Q1726L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV56757396; called by muse, mutect2, varscan2
- DNAI3 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs149091067; called by muse, mutect2, varscan2
- EPHA2 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as rs754656950, COSV64452467; called by muse, mutect2, varscan2
- FAM111A | c.1003G>T p.G335W | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV64655176; called by muse, mutect2, varscan2
- FBN1 | c.6302C>T p.T2101M | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.322); catalogued as rs200816828, CM020692; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2
- FZD2 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs770035472, COSV59528209, COSV59528679; called by muse, mutect2, varscan2
- GDF7 | c.1154C>A p.P385H | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55347362; called by muse, mutect2, varscan2
- H2BC5 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.132); catalogued as rs757195477, COSV56800337; called by muse, mutect2, varscan2
- HSP90AA1 | c.455C>T p.T152I | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV53487951; called by muse, mutect2, varscan2
- IPO5 | c.1091T>C p.M364T | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV55153099; called by muse, mutect2, varscan2
- LATS1 | c.2770C>T p.R924* | Nonsense Mutation (SNP) | VAF 25/96 reads (26%) | catalogued as rs145871963; called by muse, mutect2, varscan2
- LDLRAD3 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV59680323; called by muse, mutect2, varscan2
- LRRC55 | c.222C>A p.H74Q | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.538); catalogued as COSV73006403; called by muse, mutect2, varscan2
- LRRC55 | c.223A>G p.N75D | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV73006405; called by muse, mutect2, varscan2
- OR8B4 | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV62069483; called by muse, mutect2, varscan2
- PIR | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs757971715, COSV66815204; called by muse, mutect2, varscan2
- PPM1F | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs549205418, COSV54283229; called by muse, mutect2, varscan2
- PRKG2 | c.111G>T p.L37F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV52321539; called by muse, mutect2, varscan2
- RBM25 | c.2161G>C p.D721H | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as COSV56199159; called by muse, mutect2, varscan2
- SECISBP2 | c.1863C>G p.F621L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60527920, COSV60530121; called by muse, mutect2, varscan2
- SLC22A6 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs765937223, COSV64559988; called by muse, mutect2, varscan2
- SLC9A1 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as COSV56052361; called by muse, mutect2, varscan2
- SLCO6A1 | c.118A>G p.K40E | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.055); catalogued as COSV65807885; called by muse, mutect2, varscan2
- SRSF1 | c.416A>G p.D139G | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51964511; called by muse, mutect2, varscan2
- SRSF5 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs746899808, COSV67936578; called by muse, mutect2, varscan2
- TRIM16L | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.299); catalogued as rs752949316, COSV67459249; called by muse, mutect2, varscan2
- VWA3B | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.425); catalogued as COSV68241836; called by muse, mutect2, varscan2
- ZNF417 | c.704C>G p.T235S | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV56307851; called by muse, mutect2, varscan2
- ZNF784 | c.944C>A p.A315E | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV57595818; called by muse, varscan2
- STK11 | c.157del p.D53Tfs*11 | Frame Shift Del (DEL) | VAF 88/163 reads (54%) | called by mutect2, pindel, varscan2
- YARS1 | c.1049_1055del p.M350Kfs*38 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, varscan2
- ZNF784 | c.936_937del p.E313Dfs*21 | Frame Shift Del (DEL) | VAF 28/102 reads (27%) | called by pindel, varscan2
- ADAMTS9 | c.4716C>T p.G1572= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs376962279; called by muse, mutect2, varscan2
- B4GALT7 | c.381C>T p.H127= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV50352931; called by muse, mutect2
- CDH7 | c.1083G>A p.T361= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1445461161, COSV59883397; called by muse, varscan2
- IQCJ-SCHIP1 | c.357C>T p.A119= (on ENST00000485419 / NM_001197113.1; = p.A43= on NM_014575.3) | Silent (SNP) | VAF 36/174 reads (21%) | catalogued as COSV61841331; called by muse, mutect2, varscan2
- ITGA9 | c.2502A>T p.S834= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV53239103; called by muse, mutect2, varscan2
- MAP3K21 | c.927C>A p.A309= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV64043830; called by muse, mutect2, varscan2
- MTMR3 | c.2250G>A p.L750= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV60302797; called by muse, mutect2, varscan2
- PLCD4 | c.1785G>A p.Q595= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV68743300; called by muse, mutect2, varscan2
- PPP1R13L | c.1779G>A p.P593= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as rs148594569; called by muse, mutect2, varscan2
- SATL1 | c.1023C>T p.Y341= (on ENST00000395409; = p.Y528= on NM_001012980.2) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV60575969; called by mutect2, varscan2
- TLR2 | c.36G>A p.G12= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV52605558; called by muse, mutect2, varscan2
- TTC33 | c.393G>A p.Q131= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as COSV61802384; called by muse, mutect2, varscan2
- CTBP2 | c.58+12913C>T | Intron (SNP) | VAF 14/31 reads (45%) | catalogued as COSV58340190; called by muse, mutect2, varscan2
- ITGB4 | c.4558+375C>T | Intron (SNP) | VAF 123/244 reads (50%) | catalogued as rs148725082, COSV52323363; called by muse, mutect2, varscan2
- MEF2A | c.390+95C>T | Intron (SNP) | VAF 31/114 reads (27%) | catalogued as rs766481815, COSV57531299; called by muse, mutect2, varscan2
